Somatic mutation profile of tumor specimen BA2811D (aliquot aq-BA2811D) from BEATAML1.0 case 2448, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.0 years (17,516 days).
Specimen BA2811D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 364121aa-91f5-43e6-ba12-d177c4fded18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2696D (Solid Tissue Normal), aliquot aq-BA2696D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c61aeef-f0f4-4d94-879d-1762e2b339b4

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Frame Shift Del 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SGCA | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs758647756, CM971332, COSV100006938; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NLRP12 | c.2306del p.N769Ifs*4 | Frame Shift Del (DEL) | VAF 115/345 reads (33%) | catalogued as COSV60745961; called by mutect2, pindel, varscan2
- FAM135A | c.4001del p.R1334Lfs*56 (on ENST00000370479 / NM_001351599.1; = p.R1121Lfs*56 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 45/131 reads (34%) | called by mutect2, pindel, varscan2
- CSTF2 | c.1719C>A p.S573= | Silent (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- DLG5 | c.4623C>T p.L1541= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs746072033; called by muse, mutect2, varscan2
- KSR1 | c.1680G>A p.P560= (on ENST00000644974 / NM_001367810.1; = p.P445= on NM_014238.2) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs751567695, COSV52034342; called by muse, mutect2, varscan2
